Somatic mutation profile of tumor specimen TCGA-CH-5794-01A (aliquot TCGA-CH-5794-01A-11D-1576-08) from TCGA case TCGA-CH-5794, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Prostate gland; Age at diagnosis: 65.5 years (23,924 days).
Specimen TCGA-CH-5794-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 33543602-4480-4ba4-a503-8b2fb9e9261f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CH-5794-10A (Blood Derived Normal), aliquot TCGA-CH-5794-10A-01D-1577-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d2b8a3f7-dfe8-4b7b-b51e-0a085b6db471

The open-access MAF lists 33 somatic variants for this specimen: 22 protein-altering or splice-affecting, 10 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 18, Silent 10, Nonsense Mutation 1, Splice Region 1, Frame Shift Ins 1, In Frame Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS19 | c.1652A>C p.N551T | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.46); catalogued as COSV50734454, COSV50812200; called by muse, mutect2, varscan2
- AGFG1 | c.569A>C p.Q190P | Missense Mutation (SNP) | VAF 62/269 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.014); catalogued as COSV59515429; called by muse, mutect2, varscan2
- CCDC121 | c.284A>G p.N95S | Missense Mutation (SNP) | VAF 173/525 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as COSV53118209; called by muse, mutect2, varscan2
- FIBCD1 | c.849G>T p.T283= | Splice Region (SNP) | VAF 10/30 reads (33%) | catalogued as COSV53395878; called by muse, mutect2, varscan2
- H4C12 | c.5C>G p.S2C | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.7); catalogued as COSV62744055; called by mutect2, varscan2
- HCRTR2 | c.1289G>A p.S430N | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.003); catalogued as rs926491439, COSV104426483, COSV63799528; called by muse, mutect2, varscan2
- IGHMBP2 | c.856C>T p.R286W | Missense Mutation (SNP) | VAF 42/191 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs751421003, COSV54825896; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- JAK1 | c.2222G>A p.G741D | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV61097641; called by muse, mutect2, varscan2
- KRTAP5-5 | c.181G>A p.G61S | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as rs1167185109, COSV68785274; called by muse, mutect2, varscan2
- LRCH4 | c.1946C>T p.A649V | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs763893611, COSV56166968; called by muse, mutect2
- NF2 | c.272C>T p.P91L | Missense Mutation (SNP) | VAF 36/130 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.15); catalogued as COSV58525884, COSV58532653; called by muse, mutect2, varscan2
- NKX3-1 | c.530A>G p.Y177C | Missense Mutation (SNP) | VAF 85/360 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373263457; called by muse, mutect2, varscan2
- NOVA1 | c.1183A>T p.T395S | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as COSV57489897; called by muse, mutect2, varscan2
- OLFM2 | c.737G>A p.R246H | Missense Mutation (SNP) | VAF 8/34 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.922); catalogued as rs778468182, COSV53434053; called by muse, mutect2
- PCNX1 | c.3118G>A p.V1040I | Missense Mutation (SNP) | VAF 112/359 reads (31%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.972); catalogued as rs750339361, COSV53103820; called by muse, mutect2, varscan2
- RAI14 | c.2720C>G p.S907* | Nonsense Mutation (SNP) | VAF 31/119 reads (26%) | catalogued as COSV54305366; called by muse, varscan2
- VGLL4 | c.8C>T p.T3M | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as rs376550793; called by muse, mutect2, varscan2
- XRCC6 | c.1715C>T p.T572M | Missense Mutation (SNP) | VAF 37/171 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.194); catalogued as COSV63753380; called by muse, mutect2, varscan2
- ZNF182 | c.383C>A p.T128K | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT tolerated (0.94); PolyPhen benign (0.001); catalogued as COSV59360152; called by muse, mutect2
- ZNF528 | c.1305G>T p.K435N | Missense Mutation (SNP) | VAF 39/156 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.842); catalogued as rs780275929, COSV64621632; called by muse, mutect2, varscan2
- FMNL3 | c.2745_2747del p.F915_P916delinsL | In Frame Del (DEL) | VAF 14/98 reads (14%) | called by mutect2, pindel, varscan2
- GDPD5 | c.1332dup p.A445Rfs*32 | Frame Shift Ins (INS) | VAF 16/92 reads (17%) | called by mutect2, pindel, varscan2
- ALDOB | c.222C>T p.I74= | Silent (SNP) | VAF 99/365 reads (27%) | catalogued as rs754735910, COSV66397246; called by muse, mutect2, varscan2
- AMIGO3 | c.1014C>T p.A338= | Silent (SNP) | VAF 19/70 reads (27%) | catalogued as COSV57538137; called by muse, mutect2, varscan2
- ATP2A2 | c.657T>A p.A219= | Silent (SNP) | VAF 114/397 reads (29%) | catalogued as COSV58048456; called by muse, mutect2, varscan2
- COPS6 | c.141C>G p.V47= | Silent (SNP) | VAF 81/299 reads (27%) | catalogued as COSV57999724; called by muse, mutect2, varscan2
- GMDS | c.1053C>T p.F351= | Silent (SNP) | VAF 4/33 reads (12%) | catalogued as rs1188237052, COSV66413744; called by muse, mutect2
- HCN1 | c.2202G>A p.P734= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as rs1172557328, COSV57518826; called by muse, mutect2, varscan2
- ITGA4 | c.1854T>C p.F618= | Silent (SNP) | VAF 67/259 reads (26%) | catalogued as rs1366285082, COSV52005286; called by muse, mutect2, varscan2
- RTCB | c.726T>C p.A242= | Silent (SNP) | VAF 49/195 reads (25%) | catalogued as COSV53281005; called by muse, mutect2, varscan2
- SLCO6A1 | c.696C>T p.F232= | Silent (SNP) | VAF 79/303 reads (26%) | catalogued as rs145273103, COSV65815979; called by muse, mutect2, varscan2
- SPTA1 | c.6729C>T p.D2243= | Silent (SNP) | VAF 100/360 reads (28%) | catalogued as rs760865650, COSV63761539; called by muse, mutect2, varscan2
- DNM1P46 | n.328G>A | RNA (SNP) | VAF 5/106 reads (5%) | called by muse, mutect2
